Gene-level copy-number profile of tumor specimen TARGET-40-PASYUK-01A from TARGET case TARGET-40-PASYUK, project TARGET-OS (Osteosarcoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Osteosarcoma, NOS; Tissue or organ of origin: Long bones of lower limb and associated joints; Age at diagnosis: 16.2 years (5,931 days).
Specimen TARGET-40-PASYUK-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TARGET-OS.ef282d52-f5c2-555b-8608-a75131da69bd.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TARGET-40-PASYUK-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 363 have no estimate.
https://portal.gdc.cancer.gov/files/7330e0f4-c900-456f-aba7-f1d03c197f4c

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 533; copy number 1: 5,630; copy number 2: 31,536; copy number 3: 15,287; copy number 4: 6,074; copy number 5: 522; copy number 6: 94; copy number 7: 168; copy number 8: 208; copy number 9: 11; copy number 10: 40; copy number 14: 140; copy number 15: 2; copy number 16: 15.

Homozygous deletions (total copy number 0; autosomes only): 13 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:116,850,277–116,965,227, 4 genes: MIR4447, AC069504.1, LINC00901, RNU5E-8P.
- chr5:166,128,498–166,155,439, 1 gene: AC114321.1.
- chr6:87,282,980–87,329,278, 2 genes: GJB7, HSPD1P10.
- chr7:38,273,587–38,300,322, 5 genes: TRGJP, TRGJP1, TRGV11, TRGVB, TRGV10.
- chr12:54,608,187–54,610,462, 1 gene: GLYCAM1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 722 genes in 22 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:72,274,552–72,275,159, 1 gene, copy number 15: GDI2P2.
- chr1:72,301,472–72,301,829, 1 gene, copy number 15: RPL31P12.
- chr2:88,811,186–89,969,335, 71 genes, copy number 14 (broad region; genes not listed).
- chr4:17,320,746–18,021,876, 14 genes, copy number 7: SNORA75B, RPS7P6, QDPR, CLRN2, NACAP5, AC006160.2, LAP3, AC006160.1, MED28, FAM184B, DCAF16, NCAPG, LCORL, KRT18P63.
- chr4:19,172,335–19,456,994, 1 gene, copy number 9 (within-gene range 2–9): LINC02438.
- chr4:19,257,951–19,938,448, 4 genes, copy number 9: AC024595.1, AC024230.1, AC110767.1, AC114728.1.
- chr4:32,583,855–35,496,003, 17 genes, copy number 5 (within-gene range 3–5): AC116611.1, MAPRE1P2, AC093606.1, AC093878.1, AC097535.2, AC097535.1, AC079772.1, AC016687.3, AC016687.2, AC016687.1, LINC02484, AC110790.1, AC093689.1, AC093913.1, AC020589.1, SEC63P2, RNU6-573P.
- chr7:10,207,670–10,239,863, 2 genes, copy number 9: AC004879.1, U3.
- chr7:43,866,558–45,076,469, 54 genes, copy number 5 (within-gene range 2–5): MRPS24, URGCP-MRPS24, URGCP, TUBG1P, UBE2D4, POLR2J4, AC004951.4, AC004951.3, AC004951.2, SPDYE1, AC004951.1, AC017116.2, POLR2J4, RASA4CP, LINC00957, DBNL, MIR6837, PGAM2, AC017116.1, POLM, MIR6838, AEBP1, MIR4649, POLD2, RNA5SP230, MYL7, GCK, YKT6, CAMK2B, AC004453.2, NUDCD3, AC004453.1, RNU6-1097P, AC004938.1, NPC1L1, DDX56, TMED4, AC004938.2, AC011894.1, OGDH, ZMIZ2, AC013436.1, PPIA, H2AZ2, LINC01952, PURB, MIR4657, AC004854.2, AC004854.1, AC004847.1, MYO1G, SNHG15, SNORA9, CCM2.
- chr7:54,752,250–55,433,742, 10 genes, copy number 5–10 (within-gene range 1–10): SEC61G, SEC61G-DT, AC006971.1, EGFR, EGFR-AS1, ELDR, AC073324.1, CALM1P2, AC073347.1, LANCL2.
- chr7:56,080,283–56,882,146, 38 genes, copy number 8 (within-gene range 1–8): PHKG1, CHCHD2, NUPR2, IFITM3P4, AC006970.1, AC006970.2, CCNJP1, AC073136.1, AC073136.2, AC093392.1, RNU6-1335P, SEPTIN14P24, CICP8, AC093392.2, RNU6-1052P, AC092423.1, AC092447.7, AC092447.10, AC092447.4, RBM22P3, AC092447.8, NMD3P2, AC092447.3, AC092447.5, VN1R25P, AC092447.2, AC092447.6, AC092447.1, AC092447.9, AC095038.5, TRIM60P16, AC095038.1, AC095038.4, AC095038.2, AC095038.3, CICP28, AC118758.2, AC118758.1.
- chr8:131,712,512–132,565,246, 7 genes, copy number 6 (within-gene range 3–6): AC060788.1, EFR3A, OC90, AC100868.1, HHLA1, KCNQ3, HPYR1.
- chr10:33,177,492–33,336,262, 1 gene, copy number 7 (within-gene range 1–7): NRP1.
- chr10:33,288,304–36,626,138, 47 genes, copy number 7: RN7SL398P, AL353600.1, AL353600.2, LINC02628, AL450313.1, LINC00838, RPL23P11, LINC02629, PARD3, Y_RNA, ELOBP4, RPL37P18, RPS12P16, PARD3-AS1, SS18L2P1, RNU6-847P, RNU6-193P, PRDX2P2, LINC02635, CUL2, MIR3611, AL392046.1, CREM, RNU7-77P, ATP6V1G1P4, AL117336.1, LINC02634, RNU6-794P, CCNY, RNU6-1167P, AL117336.2, AL603824.1, AL121749.1, GJD4, FZD8, AL121749.2, MIR4683, RPL7P37, PCAT5, LINC02630, AL355300.1, MTND5P17, MTND4P18, AL590730.1, AL590730.2, NAMPTP1, Y_RNA.
- chr10:37,523,011–42,367,974, 46 genes, copy number 5–7 (within-gene range 2–7): TACC1P1, MTND1P18, MTRNR2L7, AL132657.1, ZNF248, AL132657.2, ZNF33BP1, TLK2P2, AL135791.1, ZNF37CP, ZNF33CP, ZNF25, ZNF25-DT, Y_RNA, ZNF33A, RNU6-795P, AL161931.1, EIF3LP3, FXYD6P2, ZNF37A, AL117339.4, AL117339.3, AL117339.1, CCNYL4, AL133217.1, AL117339.2, HSD17B7P2, SEPTIN7P9, AL133216.2, RNU6-1118P, CICP9, AL133216.1, ABCD1P2, AL133173.2, PABPC1P12, SLC9B1P3, ACTR3BP5, CHEK2P5, AL133173.1, AL590623.1, KSR1P1, IGKV1OR10-1, AL031601.1, AL031601.2, PABPC1P8, BX322639.1.
- chr14:18,333,726–19,957,996, 83 genes, copy number 7 (within-gene range 4–7) (broad region; genes not listed).
- chr15:19,878,555–23,447,243, 169 genes, copy number 8 (broad region; genes not listed).
- chr15:23,565,674–23,687,305, 4 genes, copy number 9: MKRN3, AC126407.1, MAGEL2, NDN.
- chr15:98,282,075–99,733,561, 33 genes, copy number 10 (within-gene range 4–10): AC015722.1, AC015722.2, LINC02351, FAM169B, AC103968.1, IRAIN, IGF1R, AC118658.1, MIR4714, AC055807.1, AC069029.1, AC036108.1, PGPEP1L, LUNAR1, SYNM, AC036108.2, TTC23, AC036108.3, AC022819.1, LRRC28, HSP90B2P, HNRNPA1P62, AC037479.1, LINC02244, AC015660.2, AC015660.3, AC015660.1, AC015660.5, AC015660.4, RPL7P5, MEF2A, Y_RNA, LYSMD4.
- chr17:12,390,738–12,395,177, 1 gene, copy number 8: AC084167.1.
- chr19:21,709,522–23,512,656, 90 genes, copy number 5 (broad region; genes not listed).
- chr21:12,999,676–13,793,141, 28 genes, copy number 6: AP001464.1, ANKRD30BP2, RNU6-614P, ZNF355P, AJ239321.1, AJ239318.1, FGF7P2, ANKRD30BP1, MIR3156-3, GTF2IP2, VN1R8P, LINC01674, SNX19P1, OR4K11P, OR4K12P, POTED, RNU6-286P, MIR3118-1, AL050303.2, GRAMD4P1, CXADRP1, AL050303.3, LONRF2P5, MIR8069-2, FEM1AP1, AL050303.1, TERF1P1, FAM207CP.

Autosomal genes at a single copy (total copy number 1): 5,571. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
